Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A7AZ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A7AZ-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT PELVIC LYMPH NODES:
Eight lymph nodes, no tumor present. (0/8)
(B) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.
(C) RIGHT PELVIC LYMPH NODES:
Six lymph nodes, no tumor present. (0/6)

CCCF ICD-O-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site: Prostate NOS, C61.9
JW 8/22/13

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) LEFT PELVIC LYMPH NODES – Consists of a single red-yellow fragment of fibroadipose tissue (12 x 6 x 1.5 cm). The section reveals eight possible lymph nodes ranging in size from 0.2 cm to 9.5 cm in greatest dimension. All lymph node candidates are entirely submitted.

SECTION CODE: A1, two lymph node candidates; A2, two lymph node candidates; A3, one lymph node candidate; A4, one lymph node candidate bisected; A5, one lymph node candidate bisected; A6-A19, largest lymph node serially sectioned.

(B) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

(C) RIGHT PELVIC LYMPH NODES – Consists of a single red-yellow fragment of fibroadipose tissue (12 x 6 x 1 cm). The section reveals six possible lymph nodes ranging in size from 0.5 cm to 8 cm in greatest dimension. All lymph node candidates are entirely submitted.

SECTION CODE: C1, four possible lymph nodes; C2, one lymph node candidate bisected; C3-C13, one lymph node candidate serially sectioned.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(B) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4+3). (SEE COMMENT)

TUMOR EXTENDING INTO EXTRAPROSTATIC TISSUE.

Margins of resection free of tumor.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

PERINEURAL INVASION PRESENT.

No lymphovascular invasion identified.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.

COMMENT

The prostate gland contains two foci of prostatic adenocarcinoma, one in the peripheral zone and one in the transition zone. The dominant tumor focus is located in the right anterolateral, right lateral, right posterolateral, right posterior, mid posterior, and left posterior peripheral zone. This tumor focus measures 2.5 x 1.6 cm in the largest cross-sectional dimension and it is present in the two cross sections of the prostate, extensively in the apex and focally in the base region. This tumor exhibits extensive multifocal extraprostatic extension. Extraprostatic extension is present in the right anterolateral and right lateral surface of the prostate and in the right superior neurovascular bundle region. Extraprostatic extension is present in multiple sections and the added length of extraprostatic extension is 5.0 mm. The margins of resection are free of tumor. The second tumor focus is located in the right and left transition zone. This tumor focus measures 1.6 x 0.5 cm in the largest cross-sectional dimension and it is present in the two cross sections of the prostate and focally in the apex and base regions. This tumor focus is of lower histologic grade and confined to the prostate. All margins of resection are free of tumor.

GROSS DESCRIPTION

(B) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.4 x 3.0 x 3.7 cm, 30 grams, post-fixation) has the usual shape. The soft tissue present along the right posterolateral aspect of the prostate appears more abundant than along the left side. A nodule is palpated in the right base region. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the right side of the two cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: B1-B4, right seminal vesicle and segment of right vas deferens from the base towards the tip; B5-B7, left seminal vesicle and segment of left vas deferens from the base towards the tip; B8, B9, prostatic base right border; B10-B13,

[page 3 of 3]
Specimen Date/Time:

prostatic base right posterior border; B14-B17, prostatic base central portion; B18, prostatic base left border; B19-B21, prostatic base left posterior border; B22, B23, apex anterior; B24, B25, apex left; B26-B29, apex posterior; B30, B31, apex right; B32, detached portions of margin of resection according to specimen radiograph; B33-B40, sections of the two cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (B22 and 23) and orange ink (B35, 36, 39 and 40) denote surfaces that do not represent a true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by:

-----END OF REPORT-----

HIIPA Discrepancy		☒

Source: NCI Genomic Data Commons file 0b221e54-686e-425b-9fca-c4c51e97282e (TCGA-KK-A7AZ.5DEA3530-6618-4A73-94C7-F23DA06DA52C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).